Gene-level copy-number profile of tumor specimen ALCH-B2RF-TTP1-A from ALCHEMIST case ALCH-B2RF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.8 years (26,239 days).
Specimen ALCH-B2RF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 585eb39e-a400-4baa-bf4b-401fb577cf4d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2RF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,269 have no estimate.
https://portal.gdc.cancer.gov/files/0a8f3636-e63b-476d-bec2-7096bde1a66e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 445; copy number 2: 56,049; copy number 3: 1,819; copy number 4: 31; copy number 5: 1; copy number 6: 3; copy number 7: 1; copy number 11: 3; copy number 18: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:142,620,373–142,621,064, 1 gene: AP006547.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:75,391,955–75,416,787, 3 genes, copy number 11 (within-gene range 2–23): AC211486.1, TRIM73, NSUN5P1.
- chr9:65,189,995–65,285,209, 4 genes, copy number 6–18: BMS1P12, AL512605.1, AL512605.2, FOXD4L5.
- chr14:18,333,726–18,341,859, 1 gene, copy number 7: CR383658.1.
- chr19:544,034–549,924, 1 gene, copy number 5: GZMM.

Autosomal genes at a single copy (total copy number 1): 431. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
